Surgical pathology report (de-identified scan), TCGA case TCGA-3X-AAVE, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Alberta Health Services, specimen TCGA-3X-AAVE-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected
Time Reported
Order Number
Status

Final

Time Received
Time Transmitted
Ordering Provider
Relevant Information
Location

Report Patient
Demographics (for
verification purposes)

Name
Date of Birth:
Sex: M

CAF ICD-O-3
path Cholangiocarcinoma 8160/3
Cholangiocarcinoma & hepatocellular
Carcinoma combined 8180/3
Site: Bile duct, intrahepatic C22.1
with Liver C22.0
QD 5/21/14

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
Liver tumor at
Clinical Information
Hepatitis B, liver tumor

Diagnosis

Liver, Resection:

- Combined cholangiocarcinoma and hepatocellular carcinoma, moderately to poorly differentiated, see synoptic report
- Maximum tumor dimension 3.5cm
- Small to medium-sized vessel vascular invasion identified
- Margins of resection are negative for carcinoma
- No lymph nodes submitted or identified
- Non-neoplastic liver shows features compatible with chronic viral hepatitis B, with grade 1 inflammation and stage 3 fibrosis (Batts-Ludwig)
- Non-neoplastic liver shows multiple/frequent von Meyenburg complexes (bile duct hamartomas), see comment in synoptic

Reported by:

Electronically signed by:

Verified:

Synoptic report

CLS Intrahepatic Bile Ducts

Specimen:

Liver

PROCEDURE:

Wedge resection

TUMOR SIZE:

Greatest dimension: 3.5 cm

TUMOR FOCALITY:

Solitary (specify location): Parenchymal

HISTOLOGIC TYPE:

Combined hepatocellular and cholangiocarcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

TUMOR GROWTH PATTERN:

Mass-forming

MICROSCOPIC TUMOR EXTENSION:

Tumor confined to hepatic parenchyma

[page 2 of 3]
HEPATIC PARENCHYMAL MARGIN:

Uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 3 mm

Specify margin: Parenchymal

BILE DUCT MARGIN:

Cannot be assessed

VENOUS (LARGE VESSEL) INVASION (V):

Indeterminate

SMALL VESSEL INVASION (L):

Present

PRIMARY TUMOR (pT):

pT2a: Solitary tumor with vascular invasion

REGIONAL LYMPH NODES (pN):

pNX: Cannot be assessed

DISTANT METASTASIS (pM):

Not applicable

*ADDITIONAL PATHOLOGIC FINDINGS (select all that apply):

Chronic hepatitis (specify type): Hepatitis B Virus (HBV)

ANCILLARY STUDIES:

Immunohistochemistry: neoplastic cells are positive for cytokeratin 7 (variable, strong to moderate), cytokeratin AE1/AE3 (variable, strong to moderate), cytokeratin Cam5.2 (variable, strong to moderate), HepPar1 (focal, weak), CD10 (focal, canalicular pattern), and pCEA (focal, canalicular pattern).

*CLINICAL HISTORY:

Hepatitis B infection.

*COMMENT(S):

The tumor shows morphologic features of combined cholangiocarcinoma and hepatocellular carcinoma, in roughly equal proportions. Although immunophenotype is predominantly of cholangiocellular type, cytokeratin staining is weaker in areas of morphologic HCC, and focal CD10/pCEA staining is present in these areas. In addition, many bile duct hamartomas/von Meyenburg complexes (VMCs) are seen in non-neoplastic liver, as well as in direct continuity with neoplasm (no definite in situ/dysplastic transformation of VMCs is appreciated, however). Multiple VMCs is considered by many authors to represent a mild form of ductal plate malformation (DPM). Likewise, there is a documented though rare association of DPM/VMCs with cholangiocarcinoma. The significance of this finding, with regards to potential causality for (or contribution to) neoplasia, is unclear in the pathology literature. With regards to vascular invasion, scattered foci of tumor present in medium-sized portal/septal type veins are identified. "Major" venous invasion, per AJCC/CAP definition, cannot be assessed in this specimen.

Gross Description

Received is a single specimen containing the neoplasia and specimen container are labelled with the patient's name, . The cassette and identifiers are labelled with the Surgical Number

A. Specimen is received fresh. The container is designated as "A. Liver tumor". The specimen consists of a portion of liver weighing 53.1 g and measuring 8.2 x 5.0 x 3.5 cm. On the capsular surface is an area of puckering measuring 1.7 x 1.5 cm. Area is dyed orange. The resection margin is dyed blue. On sectioning a firm tan mass is identified measuring 3.5 x 2.6 x 2.6 cm. This mass corresponds to the area of capsular puckering and comes within 0.3 cm of the closest blue painted resection margin. The remainder of the liver parenchyma is grossly unremarkable.

Representative sections are submitted as follows:

- A1/2. sections the mass in relation to the area of capsular puckering
- A3. section of the mass relation to the blue painted resection margin
- A4/5. further sections of the mass
- A6. sections of grossly unremarkable liver parenchyma
- A7-A11 additional sections of unremarkable liver parenchyma

Sample and Test Request Deficiency

Minor sample and/or test request deficiency.

Location of physician not provided.

Pathologist Comment

This case was also reviewed by

Representative neoplastic block: A1. Representative non-neoplastic block: A7.

Accession Number
Encounter Number
Patient Location

Per TSS, dx discrepancy form, TCGA tumor is strictly cholangiocarcinoma - as verified with the TSS pathologist.

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

PAGE

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Mixed HCC + Cholangiocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Cholangiocarcinoma	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	This is combined HCC / cholangio CA, however only cholangio component has been sampled for the research purposes	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator

Date

Source: NCI Genomic Data Commons file da0de20b-9267-4617-b32c-ac88842ea266 (TCGA-3X-AAVE.15BF3FFE-B723-403A-AD20-CBB1D0C9E394.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).